Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0RG, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0RG-01A (Primary Tumor).

Patient:

Surg Path

CLINICAL HISTORY:

Breast mass. Infiltrating ductal carcinoma.

GROSS EXAMINATION:

A. "Left breast and axillary contents". Breast in formalin, axillary tail fresh. Received is a single breast that weighs 610 grams and measures 21.5 x 14.5 x 4 cm. The specimen consists of an ellipse of skin measuring 18 x 8 cm. The nipple is present. In the upper inner quadrant, there is a hard mass measuring approximately 6 1/2 x 7 x 2.5 cm. An area of firmness measuring approximately 2 x 3 x 2 cm. is present in the lower outer quadrant. Upon cross sectioning, the larger mass is firm, tan-white with multiple areas of hemorrhage. The specimen is not gritty. Both the upper outer and lower outer quadrants contain apparent abundant breast parenchyma. This tissue, although firm, is not rock hard as the above described mass. Received fresh is an axillary tail weighing 79 grams and measuring 14 x 5 1/2 x 0.8 cm. Five mobile, hard nodules are palpated within the specimen.

Block Summary:

- Block A1 - A3 - larger mass (upper inner quadrant) at point closest to deep margin.
- Block A4 - upper outer quadrant, random section
- Block A5 - lower outer quadrant, random section.
- Block A6 - lower inner quadrant, random section
- Block A7 - A9 - smaller mass (lower outer quadrant) at point closest to deep margin.
- Block A10 - nipple
- Block A11 - random section of skin.
- Block A12 - five level III lymph nodes.
- Block A13 - four level III lymph nodes.
- Block A14 - four level II lymph nodes
- Block A15 - three level II lymph nodes.
- Block A16 - one level II lymph node, bisected.
- Block A17 - two level I lymph nodes.
- Block A18 - one level I lymph node, bisected.

DIAGNOSIS:

"LEFT BREAST AND AXILLARY CONTENTS":

BREAST AND ATTACHED AXILLARY TAG WITH INVASIVE CARCINOMA, PROBABLY DUCTAL TYPE. (7.0 CM IN GREATEST DIMENSION). HISTOLOGIC GRADE 2, NUCLEAR GRADE 3. REGIONAL LYMPH NODES NEGATIVE PER CANCER, 19 EXAMINED. ALL FINAL SURGICAL MARGINS NEGATIVE FOR CANCER.

Verified by

~~Electronic~~

100-0-3
Carcinoma, infiltrating duct 8500/3
Path Site Code: breast, upper inner quadrant C:
9/12/11
QCF breast, NOS C50.9

Source: NCI Genomic Data Commons file 7f1886bd-53e3-4721-8f70-cdb791b29e96 (TCGA-B6-A0RG.0429FA9A-AD19-424C-94ED-1A902119E559.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).